Somatic mutation profile of tumor specimen TCGA-39-5028-01A (aliquot TCGA-39-5028-01A-01D-1441-08) from TCGA case TCGA-39-5028, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 75.9 years (27,707 days).
Specimen TCGA-39-5028-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e296a716-1aea-4d39-8d02-c66a26fdd784.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-39-5028-11A (Solid Tissue Normal), aliquot TCGA-39-5028-11A-01D-1441-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/898b2339-07ab-4125-b729-17ef74881257

The open-access MAF lists 167 somatic variants for this specimen: 130 protein-altering or splice-affecting, 34 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 113, Silent 34, Nonsense Mutation 8, Splice Site 7, 5'UTR 2, In Frame Del 1, Frame Shift Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.322G>A p.D108N | Missense Mutation (SNP) | VAF 11/33 reads (33%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as rs121913381, CM071585, CM973278, COSV58682998, COSV58690035, COSV58690777, COSV58726216; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- PMS2 | c.1687C>T p.R563* | Nonsense Mutation (SNP) | VAF 49/418 reads (12%) | catalogued as rs587778618, CM102799, COSV56221094, COSV56222163; ClinVar: pathogenic / not provided; called by muse, mutect2, varscan2
- ABHD10 | c.701C>G p.P234R | Missense Mutation (SNP) | VAF 58/300 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.794); catalogued as COSV56326283; called by muse, mutect2, varscan2
- AC098582.1 | c.258C>G p.I86M | Missense Mutation (SNP) | VAF 6/131 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as COSV52021271, COSV52024534; called by muse, mutect2
- ADAM9 | c.795G>C p.W265C | Missense Mutation (SNP) | VAF 219/956 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65946864; called by muse, varscan2
- ADAMTS2 | c.3415C>G p.P1139A | Missense Mutation (SNP) | VAF 34/208 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.057); catalogued as COSV52366704, COSV52392661; called by muse, mutect2, varscan2
- ADGRB3 | c.3035+1G>T p.X1012_splice | Splice Site (SNP) | VAF 20/110 reads (18%) | catalogued as COSV53259718; called by muse, mutect2, varscan2
- ADH5 | c.1119G>C p.K373N | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as rs1174133358, COSV56449072; called by muse, mutect2
- ADRA1D | c.359C>G p.S120* | Nonsense Mutation (SNP) | VAF 5/48 reads (10%) | catalogued as COSV65241960; called by muse, mutect2
- AMPD3 | c.1307C>T p.S436L (on ENST00000396553 / NM_001025389.2; = p.S445L on NM_000480.3) | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.019); catalogued as COSV67329975; called by muse, mutect2, varscan2
- ARHGAP6 | c.1207C>G p.L403V | Missense Mutation (SNP) | VAF 38/213 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as COSV57303140; called by muse, mutect2, varscan2
- BRCA1 | c.963G>T p.W321C | Missense Mutation (SNP) | VAF 20/290 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58799348; called by muse, mutect2
- BRINP3 | c.1021A>G p.I341V | Missense Mutation (SNP) | VAF 52/249 reads (21%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs781605000, COSV66540856; called by muse, mutect2, varscan2
- BUD13 | c.659A>G p.H220R | Missense Mutation (SNP) | VAF 59/243 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as COSV52770468; called by muse, mutect2, varscan2
- C19orf57 | c.1538G>A p.R513Q | Missense Mutation (SNP) | VAF 13/150 reads (9%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs754666979, COSV60970259; called by muse, mutect2
- C2orf78 | c.2101G>C p.E701Q | Missense Mutation (SNP) | VAF 14/110 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.054); catalogued as COSV68519359; called by muse, varscan2
- CA5A | c.319G>A p.D107N | Missense Mutation (SNP) | VAF 17/102 reads (17%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.94); catalogued as COSV59243207; called by muse, mutect2, varscan2
- CARD14 | c.1116G>C p.Q372H | Missense Mutation (SNP) | VAF 10/136 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as COSV60126659; called by muse, mutect2
- CATSPERD | c.2051A>G p.N684S | Missense Mutation (SNP) | VAF 17/110 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs761956459, COSV58467480; called by muse, mutect2, varscan2
- CBLN4 | c.446C>T p.A149V | Missense Mutation (SNP) | VAF 16/123 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50354301; called by muse, mutect2, varscan2
- CCDC39 | c.513C>G p.I171M | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV56493418; called by mutect2, varscan2
- CD14 | c.370G>C p.E124Q | Missense Mutation (SNP) | VAF 9/125 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.178); catalogued as COSV57370722; called by muse, mutect2
- CDC14B | c.628-1G>A p.X210_splice | Splice Site (SNP) | VAF 13/79 reads (16%) | catalogued as COSV55793871; called by muse, mutect2, varscan2
- CDC6 | c.410G>C p.R137T | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV52931427, COSV99266668; called by muse, mutect2
- CLASP1 | c.4298C>T p.T1433M | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs1348406784, COSV55317172; called by muse, mutect2, varscan2
- CNTNAP1 | c.2422G>A p.D808N | Missense Mutation (SNP) | VAF 83/500 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV52854281; called by muse, mutect2, varscan2
- CNTNAP2 | c.1821G>C p.Q607H | Missense Mutation (SNP) | VAF 15/139 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV100662811, COSV62253882; called by muse, mutect2, varscan2
- COASY | c.319C>T p.L107F | Missense Mutation (SNP) | VAF 65/337 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as COSV55899827; called by muse, mutect2, varscan2
- COL14A1 | c.2536C>A p.R846S | Missense Mutation (SNP) | VAF 26/227 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV52850114, COSV52867933; called by muse, varscan2
- CSMD3 | c.5579C>G p.A1860G (on ENST00000297405 / NM_001363185.1; = p.A1756G on NM_052900.3) | Missense Mutation (SNP) | VAF 78/333 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.547); catalogued as COSV52137596, COSV52260763, COSV52313785; called by muse, mutect2, varscan2
- CTTNBP2NL | c.706G>C p.E236Q | Missense Mutation (SNP) | VAF 10/101 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54744816; called by muse, mutect2, varscan2
- DICER1 | c.1102C>G p.L368V | Missense Mutation (SNP) | VAF 33/284 reads (12%) | SIFT tolerated (0.51); PolyPhen benign (0.056); catalogued as rs1555374747, COSV58627995; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DLGAP5 | c.2172G>T p.M724I | Missense Mutation (SNP) | VAF 29/142 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as COSV55965290, COSV99903611; called by muse, mutect2, varscan2
- DNAAF2 | c.2207C>T p.S736F | Missense Mutation (SNP) | VAF 12/114 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.042); catalogued as COSV53572051; called by muse, mutect2, varscan2
- DNAH2 | c.4715A>T p.Q1572L | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT tolerated (0.28); PolyPhen benign (0.102); catalogued as COSV66726946; called by muse, mutect2, varscan2
- DOCK7 | c.6343C>G p.Q2115E (on ENST00000635253 / NM_001367561.1; = p.Q2084E on NM_033407.3) | Missense Mutation (SNP) | VAF 22/192 reads (11%) | SIFT tolerated (0.73); PolyPhen possibly damaging (0.682); catalogued as COSV51994679, COSV52020702; called by muse, mutect2, varscan2
- EPHA6 | c.1219G>A p.E407K | Missense Mutation (SNP) | VAF 20/322 reads (6%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.992); catalogued as COSV67560246; called by muse, mutect2
- FAM135A | c.2881A>G p.T961A (on ENST00000370479 / NM_001351599.1; = p.T748A on NM_020819.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/104 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs981573797, COSV52058928; called by muse, mutect2, varscan2
- GABRA6 | c.1143A>G p.I381M | Missense Mutation (SNP) | VAF 43/219 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.382); catalogued as COSV50893407; called by muse, mutect2, varscan2
- GABRQ | c.367G>A p.E123K | Missense Mutation (SNP) | VAF 24/158 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as COSV64783828; called by muse, mutect2, varscan2
- GALNT16 | c.850A>G p.T284A | Missense Mutation (SNP) | VAF 22/104 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV61887983; called by muse, mutect2, varscan2
- GCSAM | c.98G>A p.R33K | Missense Mutation (SNP) | VAF 30/408 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.34); catalogued as rs779704083, COSV58264523; called by muse, mutect2
- GLIS1 | c.377C>T p.S126L | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.011); catalogued as rs201535528, COSV56548697; called by muse, mutect2
- GMPPA | c.1057G>T p.V353L | Missense Mutation (SNP) | VAF 38/164 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as COSV58006109, COSV58008432; called by muse, mutect2, varscan2
- GPR78 | c.350G>A p.R117H | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.883); catalogued as rs1489987195, COSV66762975; called by muse, mutect2, varscan2
- GPR78 | c.715G>C p.A239P | Missense Mutation (SNP) | VAF 21/135 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66762610, COSV66764007; called by muse, mutect2, varscan2
- GPRASP1 | c.2934G>T p.E978D | Missense Mutation (SNP) | VAF 47/123 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.935); catalogued as COSV64356437; called by muse, mutect2, varscan2
- GRIA1 | c.2128T>A p.S710T | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV53623826; called by muse, mutect2, varscan2
- GSK3A | c.784T>C p.C262R | Missense Mutation (SNP) | VAF 14/124 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55900602; called by muse, mutect2, varscan2
- HLA-DMB | c.338-1G>T p.X113_splice | Splice Site (SNP) | VAF 26/177 reads (15%) | catalogued as COSV66870952; called by muse, mutect2, varscan2
- IGLV2-14 | c.73C>T p.Q25* | Nonsense Mutation (SNP) | VAF 25/422 reads (6%) | catalogued as rs766876695; called by muse, mutect2
- ITGB4 | c.1658-1G>A p.X553_splice | Splice Site (SNP) | VAF 17/349 reads (5%) | catalogued as COSV52332466; called by muse, mutect2
- KIAA0100 | c.6554C>G p.S2185C | Missense Mutation (SNP) | VAF 6/145 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as rs1478264740, COSV56383881; called by muse, mutect2
- KIF1B | c.2818G>A p.V940M (on ENST00000377086 / NM_001365952.1; = p.V894M on NM_015074.3) | Missense Mutation (SNP) | VAF 13/191 reads (7%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.971); catalogued as rs764144206, COSV55815817; called by muse, mutect2
- KRTAP10-7 | c.737A>T p.D246V | Missense Mutation (SNP) | VAF 18/298 reads (6%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as COSV59113254; called by muse, mutect2
- LAMA2 | c.8703+2T>A p.X2901_splice | Splice Site (SNP) | VAF 29/134 reads (22%) | catalogued as COSV70354816; called by muse, mutect2, varscan2
- LARP4B | c.1810C>T p.H604Y | Missense Mutation (SNP) | VAF 14/165 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.087); catalogued as COSV60221036; called by muse, mutect2
- LRIG2 | c.1925A>C p.D642A | Missense Mutation (SNP) | VAF 19/183 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1307129278, COSV63164186; called by muse, mutect2, varscan2
- LRPPRC | c.2786G>A p.R929K | Missense Mutation (SNP) | VAF 70/187 reads (37%) | SIFT tolerated (0.76); PolyPhen benign (0.003); catalogued as COSV53243142; called by muse, mutect2, varscan2
- LTO1 | c.286G>A p.D96N | Missense Mutation (SNP) | VAF 21/129 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.065); catalogued as COSV54163574; called by muse, mutect2, varscan2
- MAPK13 | c.375G>C p.E125D | Missense Mutation (SNP) | VAF 24/148 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52984978; called by muse, mutect2, varscan2
- MAST1 | c.928G>T p.A310S | Missense Mutation (SNP) | VAF 14/135 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV52249693, COSV52254683; called by muse, mutect2, varscan2
- MTMR4 | c.3511G>T p.E1171* | Nonsense Mutation (SNP) | VAF 21/131 reads (16%) | catalogued as COSV60203680; called by muse, mutect2, varscan2
- MUC17 | c.3950C>T p.S1317L | Missense Mutation (SNP) | VAF 59/386 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.092); catalogued as rs779694206, COSV60302751; called by muse, mutect2, varscan2
- MYO1F | c.1870C>A p.R624S | Missense Mutation (SNP) | VAF 14/154 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.704); catalogued as COSV57800094; called by muse, mutect2
- MYO5C | c.3805G>C p.E1269Q | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT tolerated (0.47); PolyPhen benign (0.074); catalogued as COSV55911854, COSV99954128; called by muse, mutect2, varscan2
- MYO9A | c.505C>T p.R169C | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61857632; called by muse, mutect2
- MYT1L | c.2018A>G p.Y673C | Missense Mutation (SNP) | VAF 9/145 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.724); catalogued as COSV67732174; called by muse, mutect2
- NECTIN1 | c.898C>T p.L300F | Missense Mutation (SNP) | VAF 15/117 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV50607858; called by muse, mutect2, varscan2
- NPEPPS | c.1984C>T p.L662F | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV59105520; called by muse, mutect2
- OR10G2 | c.73C>A p.P25T | Missense Mutation (SNP) | VAF 28/178 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV73390467; called by muse, mutect2, varscan2
- OR14I1 | c.256C>G p.R86G | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV61199454, COSV61200237, COSV61200815; called by muse, mutect2, varscan2
- OR51E2 | c.164A>G p.H55R | Missense Mutation (SNP) | VAF 32/138 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.18); catalogued as COSV67808701; called by muse, mutect2, varscan2
- OR51I1 | c.99C>G p.F33L | Missense Mutation (SNP) | VAF 16/160 reads (10%) | SIFT tolerated (0.78); PolyPhen benign (0.005); catalogued as COSV100971190, COSV66507555, COSV66509218; called by muse, mutect2
- PALB2 | c.3466G>C p.D1156H | Missense Mutation (SNP) | VAF 16/182 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.174); catalogued as COSV55170221; called by muse, mutect2
- PATZ1 | c.794G>A p.R265Q | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as COSV53231207; called by muse, mutect2, varscan2
- PCDHA6 | c.833C>T p.S278L | Missense Mutation (SNP) | VAF 30/230 reads (13%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.015); catalogued as COSV65350620; called by muse, mutect2, varscan2
- PCLO | c.6163G>A p.E2055K | Missense Mutation (SNP) | VAF 19/103 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.675); catalogued as rs891407412, COSV61664897; called by muse, mutect2, varscan2
- PCLO | c.1404G>T p.K468N | Missense Mutation (SNP) | VAF 12/145 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV61664910; called by muse, mutect2
- PCNT | c.291G>C p.K97N | Missense Mutation (SNP) | VAF 7/177 reads (4%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.005); catalogued as COSV64031443, COSV64032902; called by muse, mutect2
- PHLDB2 | c.1441A>G p.K481E | Missense Mutation (SNP) | VAF 33/201 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.437); catalogued as COSV67315984; called by muse, mutect2, varscan2
- PKN2 | c.2120G>C p.R707T | Missense Mutation (SNP) | VAF 14/193 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65144594, COSV65144750; called by muse, mutect2
- PLXNB1 | c.5206G>A p.D1736N | Missense Mutation (SNP) | VAF 18/182 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1310913666, COSV56494057; called by muse, mutect2, varscan2
- PRDM13 | c.547C>A p.P183T | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.036); catalogued as COSV65030672; called by muse, mutect2, varscan2
- PREX1 | c.3655C>T p.H1219Y | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.861); catalogued as COSV64256677; called by muse, mutect2, varscan2
- PRRC1 | c.1120G>C p.V374L | Missense Mutation (SNP) | VAF 19/146 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.148); catalogued as COSV56991948; called by muse, mutect2, varscan2
- PSD2 | c.1626C>G p.F542L | Missense Mutation (SNP) | VAF 10/178 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.549); catalogued as COSV51210170; called by muse, mutect2
- PSMB11 | c.575A>T p.Y192F | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.561); catalogued as COSV57463450; called by muse, mutect2, varscan2
- PSME4 | c.2321C>T p.S774L | Missense Mutation (SNP) | VAF 77/295 reads (26%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs377459628; called by muse, varscan2
- PUM2 | c.2197G>C p.E733Q | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV57585236; called by muse, mutect2, varscan2
- RAI1 | c.5198C>T p.S1733L | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as rs752186236, COSV55398970; called by muse, mutect2, varscan2
- RBM43 | c.631C>T p.P211S | Missense Mutation (SNP) | VAF 12/186 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.155); catalogued as rs559120361, COSV58879873; called by muse, mutect2
- RNF149 | c.125T>C p.V42A | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV54865419; called by muse, mutect2
- RNF157 | c.421G>A p.E141K | Missense Mutation (SNP) | VAF 12/194 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as rs966871493, COSV53948167; called by muse, mutect2
- RPS6KC1 | c.1996G>T p.D666Y | Missense Mutation (SNP) | VAF 25/152 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV65302777; called by muse, mutect2, varscan2
- RSBN1L | c.100C>T p.R34W | Missense Mutation (SNP) | VAF 22/99 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.409); catalogued as rs376749582, COSV58511110; called by muse, mutect2, varscan2
- RSBN1L | c.1870C>T p.Q624* | Nonsense Mutation (SNP) | VAF 12/188 reads (6%) | catalogued as COSV58509433, COSV58511120; called by muse, mutect2
- RTKN2 | c.1197G>T p.K399N | Missense Mutation (SNP) | VAF 23/152 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59524443; called by muse, mutect2, varscan2
- SLC17A7 | c.1552G>T p.G518C | Missense Mutation (SNP) | VAF 18/121 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.619); catalogued as COSV55550058; called by muse, mutect2, varscan2
- SMG7 | c.2719C>T p.P907S | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.001); catalogued as COSV61634183; called by muse, mutect2, varscan2
- SPTA1 | c.5523G>T p.L1841F | Missense Mutation (SNP) | VAF 35/252 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.427); catalogued as COSV63759089; called by muse, mutect2, varscan2
- SRRM1 | c.2443_2445del p.K815del | In Frame Del (DEL) | VAF 18/78 reads (23%) | catalogued as rs777101977; called by pindel, varscan2
- TAF4 | c.2803G>C p.E935Q | Missense Mutation (SNP) | VAF 52/773 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as COSV53341721, COSV53342819; called by muse, mutect2
- TECTB | c.88G>C p.V30L | Missense Mutation (SNP) | VAF 7/89 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1200419922, COSV65596492; called by muse, mutect2
- TENM4 | c.8058G>C p.E2686D | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.97); catalogued as COSV53668600; called by muse, mutect2, varscan2
- THSD7B | c.4321C>A p.L1441I (on ENST00000272643; = p.L1439I on NM_001316349.2) | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.997); catalogued as COSV55735757; called by muse, mutect2
- TJP3 | c.1787C>G p.S596* | Nonsense Mutation (SNP) | VAF 6/71 reads (8%) | catalogued as COSV53665579; called by muse, mutect2
- TLR8 | c.2294C>A p.S765Y (on ENST00000218032 / NM_138636.5; = p.S783Y on NM_016610.4) | Missense Mutation (SNP) | VAF 9/94 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); catalogued as COSV54320553; called by muse, mutect2, varscan2
- TMEM135 | c.1030T>C p.Y344H | Missense Mutation (SNP) | VAF 21/115 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV59706435; called by muse, mutect2, varscan2
- TOR4A | c.925C>T p.R309C | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); catalogued as COSV62627636; called by muse, mutect2
- TRHR | c.1062C>G p.Y354* | Nonsense Mutation (SNP) | VAF 67/249 reads (27%) | catalogued as COSV61236424; called by muse, mutect2, varscan2
- TRIM15 | c.135G>C p.Q45H | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.012); catalogued as rs773450878, COSV64990379; called by muse, mutect2
- UGT2A3 | c.734G>T p.C245F | Missense Mutation (SNP) | VAF 18/120 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.2); catalogued as COSV52362063; called by muse, mutect2, varscan2
- UGT8 | c.1043-1G>A p.X348_splice | Splice Site (SNP) | VAF 24/151 reads (16%) | catalogued as COSV60420803; called by muse, mutect2, varscan2
- UNC13C | c.5282T>A p.L1761* | Nonsense Mutation (SNP) | VAF 44/224 reads (20%) | catalogued as COSV52922360; called by muse, mutect2, varscan2
- USP26 | c.950C>A p.P317Q | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV63708963; called by muse, mutect2, varscan2
- USP34 | c.6852G>T p.W2284C | Missense Mutation (SNP) | VAF 20/152 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as COSV101277242, COSV68406339; called by muse, mutect2, varscan2
- VPS39 | c.2566A>G p.K856E (on ENST00000348544 / NM_001301138.2; = p.K845E on NM_015289.5) | Missense Mutation (SNP) | VAF 14/420 reads (3%) | SIFT deleterious (0.03); PolyPhen benign (0.048); catalogued as COSV58793230; called by muse, mutect2
- VPS50 | c.1666G>C p.E556Q | Missense Mutation (SNP) | VAF 7/116 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.146); catalogued as COSV58511169; called by muse, mutect2
- ZFAND4 | c.1625C>T p.S542F | Missense Mutation (SNP) | VAF 36/261 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60861301; called by muse, mutect2, varscan2
- ZMAT1 | c.1309C>A p.H437N | Missense Mutation (SNP) | VAF 138/359 reads (38%) | SIFT tolerated (0.28); PolyPhen benign (0.042); catalogued as rs1437236715, COSV65660075; called by muse, mutect2, varscan2
- ZNF513 | c.200G>C p.R67T | Missense Mutation (SNP) | VAF 24/564 reads (4%) | SIFT tolerated (0.19); PolyPhen benign (0.019); catalogued as COSV52010391; called by muse, mutect2
- ZNF614 | c.163G>C p.D55H | Missense Mutation (SNP) | VAF 17/170 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as rs1402267113, COSV54548275; called by muse, mutect2
- ZNF616 | c.517G>T p.G173C | Missense Mutation (SNP) | VAF 22/243 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.017); catalogued as COSV57513250; called by muse, mutect2
- ZNF623 | c.316C>G p.L106V | Missense Mutation (SNP) | VAF 12/228 reads (5%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.869); catalogued as COSV101513572, COSV71697356; called by muse, mutect2
- ZNF669 | c.713G>T p.R238I | Missense Mutation (SNP) | VAF 23/264 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.444); catalogued as COSV58539293; called by muse, mutect2
- ASAH2 | c.1902C>G p.F634L | Missense Mutation (SNP) | VAF 22/490 reads (4%) | SIFT tolerated (0.35); PolyPhen benign (0.07); called by muse, mutect2
- CCL14 | c.164C>G p.T55S (on ENST00000618404 / NM_032963.4; = p.T71S on NM_032962.4) | Missense Mutation (SNP) | VAF 16/109 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- OR13C2 | c.280del p.L94Ffs*24 | Frame Shift Del (DEL) | VAF 22/135 reads (16%) | called by mutect2, varscan2
- PKLR | c.376-2dup p.X126_splice | Splice Site (INS) | VAF 14/57 reads (25%) | called by mutect2, pindel, varscan2
- ALCAM | c.909G>A p.V303= | Silent (SNP) | VAF 22/104 reads (21%) | catalogued as COSV60254778; called by muse, mutect2, varscan2
- ANKMY1 | c.636C>T p.I212= | Silent (SNP) | VAF 25/258 reads (10%) | catalogued as COSV56040727; called by muse, mutect2
- CPT1C | c.1716A>G p.Q572= | Silent (SNP) | VAF 10/84 reads (12%) | catalogued as COSV54922086; called by muse, mutect2, varscan2
- DCAF8L1 | c.1125A>T p.V375= | Silent (SNP) | VAF 16/64 reads (25%) | catalogued as COSV71595521; called by muse, varscan2
- DEPDC7 | c.904C>T p.L302= (on ENST00000241051 / NM_001077242.2; = p.L293= on NM_139160.2) | Silent (SNP) | VAF 21/142 reads (15%) | catalogued as COSV53809224; called by muse, mutect2, varscan2
- DNAH8 | c.3261G>C p.L1087= | Silent (SNP) | VAF 19/104 reads (18%) | catalogued as COSV59479168; called by muse, mutect2, varscan2
- DOCK8 | c.1590G>C p.V530= | Silent (SNP) | VAF 11/180 reads (6%) | catalogued as COSV66636020; called by muse, mutect2
- ELP4 | c.666C>A p.T222= (on ENST00000350638; = p.T221= on NM_019040.5) | Silent (SNP) | VAF 23/156 reads (15%) | catalogued as COSV63358304; called by muse, mutect2, varscan2
- ESYT3 | c.463C>T p.L155= | Silent (SNP) | VAF 23/132 reads (17%) | catalogued as COSV100004888, COSV56681869; called by muse, mutect2, varscan2
- EZH2 | c.1014C>G p.L338= (on ENST00000460911 / NM_001203247.2; = p.L343= on NM_004456.5) | Silent (SNP) | VAF 19/301 reads (6%) | catalogued as COSV57462504; called by muse, mutect2
- GPATCH2L | c.702C>G p.L234= | Silent (SNP) | VAF 11/65 reads (17%) | catalogued as COSV55051271; called by muse, mutect2, varscan2
- GRSF1 | c.552T>C p.F184= | Silent (SNP) | VAF 8/105 reads (8%) | catalogued as COSV54657165; called by muse, mutect2
- IGKV1-9 | c.30G>T p.L10= | Silent (SNP) | VAF 22/252 reads (9%) | called by muse, mutect2
- IL37 | c.420G>A p.L140= | Silent (SNP) | VAF 10/138 reads (7%) | catalogued as COSV54492972; called by muse, mutect2
- JAK3 | c.1287C>T p.L429= | Silent (SNP) | VAF 4/35 reads (11%) | catalogued as rs748032555, COSV71687626; called by muse, mutect2
- KATNB1 | c.231C>G p.L77= | Silent (SNP) | VAF 12/158 reads (8%) | catalogued as COSV65561848; called by muse, mutect2
- KIDINS220 | c.5031C>T p.N1677= | Silent (SNP) | VAF 8/134 reads (6%) | catalogued as COSV56758924; called by muse, mutect2
- MAP3K12 | c.1566G>A p.L522= | Silent (SNP) | VAF 12/114 reads (11%) | catalogued as COSV57232978, COSV99913472; called by muse, mutect2
- MUC17 | c.4062C>T p.I1354= | Silent (SNP) | VAF 62/423 reads (15%) | catalogued as COSV60302762; called by muse, mutect2, varscan2
- OR14K1 | c.126C>A p.V42= | Silent (SNP) | VAF 28/156 reads (18%) | catalogued as COSV51722195, COSV99315387; called by muse, mutect2, varscan2
- OR8A1 | c.447C>T p.Y149= | Silent (SNP) | VAF 18/100 reads (18%) | catalogued as rs751500437, COSV52508166; called by muse, mutect2, varscan2
- PCDHB13 | c.1809G>A p.S603= | Silent (SNP) | VAF 3/118 reads (3%) | catalogued as COSV99506647; called by muse, mutect2
- PCDHGC3 | c.900A>T p.V300= | Silent (SNP) | VAF 23/201 reads (11%) | catalogued as COSV52767574; called by muse, mutect2, varscan2
- PHF20 | c.3024C>T p.L1008= | Silent (SNP) | VAF 14/93 reads (15%) | catalogued as COSV64977828; called by muse, mutect2, varscan2
- PLEKHM1 | c.3105G>T p.V1035= | Silent (SNP) | VAF 18/112 reads (16%) | catalogued as COSV69599413; called by muse, mutect2, varscan2
- PSEN1 | c.1272C>T p.L424= | Silent (SNP) | VAF 32/499 reads (6%) | catalogued as rs200547750, COSV56196908; called by muse, mutect2
- PTN | c.225G>A p.E75= | Silent (SNP) | VAF 14/110 reads (13%) | catalogued as COSV61969638; called by muse, mutect2, varscan2
- RETNLB | c.51G>A p.L17= | Silent (SNP) | VAF 22/88 reads (25%) | catalogued as COSV55465265; called by muse, mutect2, varscan2
- RNF7 | c.279G>A p.V93= | Silent (SNP) | VAF 12/148 reads (8%) | catalogued as COSV56422317; called by muse, mutect2
- STYXL2 | c.645G>A p.L215= | Silent (SNP) | VAF 12/61 reads (20%) | catalogued as rs1558024399, COSV54809834; called by muse, mutect2, varscan2
- TGM6 | c.1485C>T p.I495= | Silent (SNP) | VAF 6/82 reads (7%) | catalogued as rs1464780010, COSV52483350; called by muse, mutect2
- THBS3 | c.1005C>T p.T335= | Silent (SNP) | VAF 22/164 reads (13%) | catalogued as rs768801703, COSV64250824; called by muse, mutect2, varscan2
- TMEM266 | c.411G>A p.V137= | Silent (SNP) | VAF 29/386 reads (8%) | catalogued as COSV66381666; called by muse, mutect2
- WNT3A | c.246C>T p.R82= | Silent (SNP) | VAF 10/71 reads (14%) | catalogued as rs764558716, COSV52733989; called by muse, mutect2, varscan2
- STAG2 | c.3467+148G>T | Intron (SNP) | VAF 9/40 reads (23%) | catalogued as COSV99494879; called by muse, mutect2
- ZNF324B | c.-25G>A | 5'UTR (SNP) | VAF 5/25 reads (20%) | catalogued as rs1396015239, COSV100351665, COSV100351761, COSV100351845; called by muse, mutect2
- ZNF521 | c.-119G>A | 5'UTR (SNP) | VAF 7/114 reads (6%) | catalogued as rs1400887407, COSV100833078; called by muse, mutect2
